Somatic mutation profile of tumor specimen C3L-02179-01 (aliquot CPT0389320006) from CPTAC case C3L-02179, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 82.3 years (30,070 days).
Specimen C3L-02179-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7371f0d2-ef1f-4650-868e-8c1678f536e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02179-31 (Blood Derived Normal), aliquot CPT0389350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b83882c-4483-4278-aef0-c47591f507d9

The open-access MAF lists 91 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Intron 7, Frame Shift Del 5, 3'UTR 3, Frame Shift Ins 3, 5'UTR 2, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TUBA1A | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1565627253, CM111879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALX3 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768080424; called by muse, mutect2, varscan2
- CD68 | c.911A>C p.H304P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51509861; called by muse, mutect2, varscan2
- COL22A1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370563319; called by muse, mutect2, varscan2
- DMD | c.6697A>G p.I2233V | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100629421; called by muse, mutect2, varscan2
- DNAI4 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs898246955; called by muse, mutect2, varscan2
- EPYC | c.656G>C p.S219T | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); catalogued as rs139254082; called by muse, mutect2, varscan2
- KIF20B | c.4132C>G p.R1378G (on ENST00000371728 / NM_001284259.2; = p.R1338G on NM_016195.4) | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV53312333; called by muse, mutect2, varscan2
- MAPKAP1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs756247676; called by muse, mutect2, varscan2
- PCDHAC1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs782052342; called by muse, mutect2
- PRB4 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as COSV54396032; called by muse, mutect2
- PTCH1 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs144501989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A22 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs748985316; called by muse, mutect2
- SPATA31D1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV61196632; called by muse, mutect2, varscan2
- ZNF835 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV73379402; called by muse, mutect2
- AEBP1 | c.2911T>C p.Y971H | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AIRE | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANAPC2 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B4GALNT1 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- BTN3A1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- C1S | c.1894A>T p.S632C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDC42BPG | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2
- CFAP20DC | c.617_620dup p.V209Rfs*13 (on ENST00000482387 / NM_001351530.2; = p.V84Rfs*13 on NM_198463.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 41/134 reads (31%) | called by mutect2, pindel, varscan2
- CIT | c.5731C>T p.H1911Y | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CTNND1 | c.1129T>A p.F377I | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2
- CTNND1 | c.1131C>G p.F377L | Missense Mutation (SNP) | VAF 90/386 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2
- CYP26A1 | c.1143dup p.E382* | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- DLX2 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EGLN3 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- F2R | c.360_365del p.N120_M122delinsK | In Frame Del (DEL) | VAF 66/350 reads (19%) | called by mutect2, pindel, varscan2
- FGD2 | c.1294dup p.Q432Pfs*4 | Frame Shift Ins (INS) | VAF 42/148 reads (28%) | called by mutect2, pindel, varscan2
- GABBR1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- GNAT3 | c.298A>C p.S100R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HLA-DQB2 | c.598_613del p.C200Pfs*23 (on ENST00000435145; = p.C200Pfs*26 on NM_001198858.2) | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by pindel, varscan2*
- IGLV3-10 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- LEMD3 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEMD3 | c.1071C>G p.Y357* | Nonsense Mutation (SNP) | VAF 142/334 reads (43%) | called by muse, mutect2, varscan2
- LRRN4 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- MAPK12 | c.683del p.G228Afs*8 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- MB | c.438C>A p.N146K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- MGAM2 | c.4826T>C p.M1609T | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MGAT1 | c.1307C>A p.T436K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NF2 | c.491_500del p.A164Dfs*7 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | called by mutect2, pindel, varscan2
- OR6C70 | c.411del p.V138Ffs*11 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- PAPOLA | c.1337C>G p.T446R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- POLR1C | c.794_805+19del p.X265_splice | Splice Site (DEL) | VAF 24/270 reads (9%) | called by mutect2, pindel
- PPP4R3C | c.1407T>A p.H469Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RD3L | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- REPIN1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- RMDN3 | c.417del p.R140Efs*61 | Frame Shift Del (DEL) | VAF 65/308 reads (21%) | called by mutect2, pindel, varscan2
- RNF14 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RNF207 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- RTKN2 | c.1711A>C p.S571R | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SEMA4F | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETD2 | c.4982A>G p.E1661G | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIPA1L1 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.12380A>G p.D4127G | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT1A9 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- XRCC5 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZFPM2 | c.1108T>A p.F370I | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF606 | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN29 | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- C1S | c.1896T>C p.S632= | Silent (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2
- CARD11 | c.1995G>T p.S665= | Silent (SNP) | VAF 14/277 reads (5%) | called by muse, mutect2
- CHEK2 | c.981C>T p.C327= (on ENST00000382580 / NM_001005735.2; = p.C284= on NM_007194.4) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1555917031; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOLPP1 | c.204G>A p.L68= | Silent (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- KASH5 | c.1629G>A p.P543= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs545376048; called by muse, varscan2
- KMT2D | c.8694G>A p.Q2898= | Silent (SNP) | VAF 155/329 reads (47%) | called by muse, mutect2, varscan2
- MUC12 | c.1824G>A p.S608= (on ENST00000379442; = p.S465= on NM_001164462.1) | Silent (SNP) | VAF 92/527 reads (17%) | catalogued as rs1224122217; called by muse, mutect2, varscan2
- NLRP8 | c.834C>T p.P278= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as rs762189376, COSV52584959; called by muse, mutect2, varscan2
- NOL6 | c.1608C>T p.D536= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV53041003; called by muse, mutect2, varscan2
- NOTCH3 | c.2451C>T p.P817= | Silent (SNP) | VAF 61/192 reads (32%) | catalogued as rs757662917, COSV54636814; called by muse, mutect2, varscan2
- PER2 | c.412T>C p.L138= | Silent (SNP) | VAF 75/276 reads (27%) | called by muse, mutect2, varscan2
- PLD2 | c.1869C>A p.L623= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, varscan2
- PTPRB | c.1227G>T p.R409= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV54255546; called by muse, mutect2, varscan2
- RALB | c.42C>A p.L14= | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- TMEM132D | c.1695C>A p.G565= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs1465969977; called by muse, mutect2, varscan2
- VAX1 | c.894G>A p.S298= | Silent (SNP) | VAF 78/254 reads (31%) | catalogued as COSV53327641; called by muse, mutect2, varscan2
- ATP10A | c.3166-68del | Intron (DEL) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- CALCA | c.*17C>G | 3'UTR (SNP) | VAF 52/233 reads (22%) | called by muse, mutect2, varscan2
- CFAP221 | c.527+10433A>G | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as rs761598944; called by mutect2, varscan2
- FOXK2 | c.420-3889T>A | Intron (SNP) | VAF 61/224 reads (27%) | called by muse, mutect2, varscan2
- GTSF1 | c.488-323G>T | Intron (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- JMJD1C | c.-45del | 5'UTR (DEL) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
- LRWD1 | c.-56G>A | 5'UTR (SNP) | VAF 37/209 reads (18%) | called by muse, mutect2, varscan2
- OSTCP1 | n.353C>T | RNA (SNP) | VAF 30/185 reads (16%) | catalogued as rs1251096541; called by muse, mutect2, varscan2
- RGL4 | c.1087-22C>G | Intron (SNP) | VAF 63/169 reads (37%) | called by muse, mutect2, varscan2
- RMDN2 | c.*325T>C | 3'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- SDHA | c.63+1855A>G | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- SLC4A8 | c.-112+11702C>G | Intron (SNP) | VAF 45/159 reads (28%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*952T>A | 3'UTR (SNP) | VAF 103/339 reads (30%) | called by muse, mutect2, varscan2
